Somatic mutation profile of tumor specimen TCGA-D8-A1X6-01A (aliquot TCGA-D8-A1X6-01A-11D-A14K-09) from TCGA case TCGA-D8-A1X6, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 80.1 years (29,256 days).
Specimen TCGA-D8-A1X6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1a288f8a-7490-473f-bca2-31d7c6d7f329.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D8-A1X6-10A (Blood Derived Normal), aliquot TCGA-D8-A1X6-10A-01D-A14K-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4aae0a55-1072-44ac-82b0-e6fadebfc5f3

The open-access MAF lists 36 somatic variants for this specimen: 30 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 5, Frame Shift Ins 3, Nonsense Mutation 1, Intron 1, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTL6B | c.967G>C p.G323R | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.724); catalogued as COSV50513811; called by muse, mutect2
- ADAMTS7 | c.3622C>A p.P1208T | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV66305738; called by muse, mutect2, varscan2
- ATXN7 | c.1916G>C p.C639S | Missense Mutation (SNP) | VAF 84/227 reads (37%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as COSV55747806; called by muse, mutect2, varscan2
- BRD3 | c.68C>T p.P23L | Missense Mutation (SNP) | VAF 31/45 reads (69%) | SIFT deleterious (0.02); PolyPhen benign (0.293); catalogued as rs200460874, COSV57701256, COSV57708013; called by muse, mutect2, varscan2
- EXOSC9 | c.1100T>C p.I367T | Missense Mutation (SNP) | VAF 45/108 reads (42%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV54664774; called by muse, mutect2, varscan2
- FAM214A | c.2858C>T p.P953L | Missense Mutation (SNP) | VAF 49/144 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.464); catalogued as COSV55921743; called by muse, mutect2, varscan2
- GAP43 | c.664C>T p.R222W | Missense Mutation (SNP) | VAF 63/155 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.817); catalogued as rs764694995, COSV59342228, COSV59347016; called by muse, mutect2, varscan2
- GATA3 | c.922-3_922-2del p.X308_splice | Splice Site (DEL) | VAF 41/112 reads (37%) | catalogued as rs763236375, COSV60515023; called by mutect2, pindel, varscan2
- HCFC2 | c.1984G>C p.G662R | Missense Mutation (SNP) | VAF 70/189 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57557837; called by muse, mutect2, varscan2
- KAT2B | c.1607G>A p.R536Q | Missense Mutation (SNP) | VAF 41/85 reads (48%) | SIFT tolerated (0.23); PolyPhen benign (0.049); catalogued as rs773908616, COSV55426332; called by muse, mutect2, varscan2
- KDM4C | c.145G>C p.V49L | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as COSV67183313; called by muse, mutect2, varscan2
- LIMS1 | c.941G>T p.R314I | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.944); catalogued as COSV57539057; called by muse, mutect2, varscan2
- MAP3K1 | c.954dup p.L319Tfs*7 | Frame Shift Ins (INS) | VAF 111/203 reads (55%) | catalogued as rs1169355679, COSV68128805; called by mutect2, pindel, varscan2
- MROH1 | c.2871C>T p.S957= | Splice Region (SNP) | VAF 12/80 reads (15%) | catalogued as rs1177222637; called by muse, mutect2
- MTUS2 | c.2330G>A p.R777H | Missense Mutation (SNP) | VAF 82/175 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777226951, COSV70912667; called by muse, mutect2, varscan2
- NCKAP1L | c.451C>T p.R151W | Missense Mutation (SNP) | VAF 35/186 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs749529749, COSV53203011; called by muse, mutect2, varscan2
- NFE2L2 | c.371C>G p.A124G | Missense Mutation (SNP) | VAF 50/116 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.02); catalogued as COSV67960024, COSV67961035; called by muse, mutect2, varscan2
- PCDH19 | c.856C>T p.R286C | Missense Mutation (SNP) | VAF 61/123 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV55257022; called by muse, mutect2, varscan2
- PCDHA11 | c.1715C>T p.A572V | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.003); catalogued as rs372502721, COSV56508035; called by muse, mutect2, varscan2
- PSMA3 | c.675T>A p.H225Q | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV53616192; called by muse, mutect2, varscan2
- SEC23IP | c.1388G>A p.S463N | Missense Mutation (SNP) | VAF 204/553 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.348); catalogued as COSV64830638; called by muse, mutect2, varscan2
- SPTA1 | c.178C>T p.R60* | Nonsense Mutation (SNP) | VAF 67/173 reads (39%) | catalogued as rs373695294; called by muse, mutect2, varscan2
- SVBP | c.104A>G p.Q35R | Missense Mutation (SNP) | VAF 126/322 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs1219403571, COSV65300009; called by muse, mutect2, varscan2
- TAB3 | c.1384G>A p.A462T | Missense Mutation (SNP) | VAF 37/139 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV55834065; called by muse, mutect2, varscan2
- TBX3 | c.559C>T p.H187Y | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57468991; called by muse, mutect2, varscan2
- ULBP1 | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0.065); catalogued as COSV57664907; called by muse, mutect2
- USP24 | c.4237C>T p.L1413F | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.996); catalogued as COSV53761290; called by muse, mutect2, varscan2
- VSIG8 | c.67C>T p.R23W | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749208107, COSV63652228; called by muse, mutect2, varscan2
- KMT2C | c.14288_14289dup p.K4764Gfs*3 | Frame Shift Ins (INS) | VAF 115/323 reads (36%) | called by mutect2, pindel, varscan2
- NEUROD2 | c.905dup p.L303Afs*80 | Frame Shift Ins (INS) | VAF 13/38 reads (34%) | called by mutect2, pindel, varscan2
- AMBRA1 | c.3852C>T p.S1284= (on ENST00000458649 / NM_001367468.1; = p.S1194= on NM_017749.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 21/93 reads (23%) | catalogued as COSV54048027; called by muse, mutect2, varscan2
- FOXG1 | c.1143C>T p.A381= | Silent (SNP) | VAF 12/24 reads (50%) | catalogued as COSV57394896; called by muse, mutect2, varscan2
- PLD3 | c.1347G>A p.T449= | Silent (SNP) | VAF 15/30 reads (50%) | catalogued as rs558997903, COSV52518903; called by muse, varscan2
- PNPLA7 | c.1605C>T p.T535= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as rs148879085; called by muse, mutect2, varscan2
- UGT1A6 | c.1389T>C p.F463= | Silent (SNP) | VAF 44/92 reads (48%) | catalogued as rs757417206, COSV59381010; called by muse, mutect2, varscan2
- GBA3 | c.59-8522G>A | Intron (SNP) | VAF 72/156 reads (46%) | catalogued as rs1168378156; called by muse, mutect2, varscan2
